Somatic mutation profile of tumor specimen 0E03V9 from CCDI case PBCUMP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E03V9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 372f2043-fb26-4ea5-bdda-f2d1c244b4d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E03W2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23f87014-e01c-42b5-b634-dfc36e0eb802

The open-access MAF lists 11 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 4, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIRREL3 | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 45/698 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.734); catalogued as rs751857978; called by muse, mutect2
- DLX4 | c.448C>G p.L150V (on ENST00000240306 / NM_138281.3; = p.L78V on NM_001934.3) | Missense Mutation (SNP) | VAF 26/498 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- F5 | c.1549T>G p.S517A | Missense Mutation (SNP) | VAF 30/820 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- LDHD | c.1297G>C p.V433L | Missense Mutation (SNP) | VAF 208/555 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PDZD11 | c.60T>G p.N20K | Missense Mutation (SNP) | VAF 43/862 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2
- COL5A1 | c.3753G>A p.P1251= | Silent (SNP) | VAF 157/395 reads (40%) | catalogued as rs779638584; ClinVar: likely benign; called by muse, mutect2
- KIF26B | c.2550C>T p.S850= | Silent (SNP) | VAF 10/246 reads (4%) | catalogued as rs765221697, COSV100831884; called by muse, mutect2
- MGAM | c.3588G>A p.T1196= | Silent (SNP) | VAF 33/842 reads (4%) | catalogued as rs181422456, COSV101527356; called by muse, mutect2
- ZNF655 | c.90G>A p.E30= | Silent (SNP) | VAF 56/808 reads (7%) | called by muse, mutect2
- ARAP1 | c.4335+81C>T | Intron (SNP) | VAF 64/143 reads (45%) | called by muse, mutect2, varscan2
- INTS3 | c.1237+70G>A | Intron (SNP) | VAF 27/254 reads (11%) | called by muse, mutect2, varscan2
